Somatic mutation profile of tumor specimen MP2PRT-PARKUN-TMP1-A (aliquot MP2PRT-PARKUN-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKUN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (697 days).
Specimen MP2PRT-PARKUN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b00cde1-902a-48b4-9ff4-e81647bababd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKUN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKUN-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b38e827-0b5b-46d0-bc9e-1b2782b00f74

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 142/456 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ANO7 | c.872T>C p.F291S (on ENST00000274979; = p.F237S on NM_001370694.2) | Missense Mutation (SNP) | VAF 11/315 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1244396246; called by muse, mutect2
- MYO1D | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772153912, COSV59010156; called by muse, varscan2
- MYH1 | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 106/662 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, varscan2
- MAPK4 | c.1506C>T p.G502= | Silent (SNP) | VAF 172/1418 reads (12%) | catalogued as rs1441618243; called by muse, varscan2
